MMRF case MMRF_1504 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/dca6ccf4-4840-4e29-84b8-e20a81e2b554

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 73 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 73.8 years (26,940 days); ISS stage: III; Days to last known disease status: 1,352 days (3.7 years); Days to last follow up: 1,352 days (3.7 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 84 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 11 days; Days to treatment end: 158 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 84 days; Days to treatment end: 152 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 84 days; Days to treatment end: 309 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 179 days; Days to treatment end: 262 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 309 days; Days to treatment end: 675 days (1.8 years).
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: Second line of therapy; Days to treatment start: 1,082 days (3.0 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 1,082 days (3.0 years); Days to treatment end: 1,345 days (3.7 years).
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: Third line of therapy; Days to treatment start: 1,345 days (3.7 years).

Follow-up (1 entry)
- Follow-up contact recording only the day: day 1,352.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -7 (ECOG 0): M Protein 5.78 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 114 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.2 mg/dL; Immunoglobulin G 2.34 g/L; Immunoglobulin A 70.3 g/L; Immunoglobulin M 0.07 g/L; Beta 2 Microglobulin 8.8 µg/mL; Hemoglobin 4.22 mmol/L; Leukocytes 2.9 ×10⁹/L; Absolute Neutrophil 1.8 ×10⁹/L; Platelets 130 ×10⁹/L; Creatinine 133 µmol/L; Blood Urea Nitrogen 9.28 mmol/L; Calcium 2.3 mmol/L; Albumin 31 g/L; Total Protein 11.8 g/dL; Glucose 5.5 mmol/L; C-Reactive Protein 0.2 mg/dL.
- Day 84 (ECOG 0): M Protein 0.66 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.39 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.18 mg/dL; Immunoglobulin G 5.35 g/L; Immunoglobulin A 1.11 g/L; Immunoglobulin M 0.25 g/L; Lactate Dehydrogenase 3.63 µkat/L; Hemoglobin 6.7 mmol/L; Leukocytes 4.3 ×10⁹/L; Absolute Neutrophil 3.7 ×10⁹/L; Platelets 162 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.05 mmol/L; Albumin 33 g/L; Total Protein 6.4 g/dL; Glucose 6.11 mmol/L.
- Day 172 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.02 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.03 mg/dL; Immunoglobulin G 5.31 g/L; Immunoglobulin A 0.71 g/L; Immunoglobulin M 0.25 g/L; Hemoglobin 6.94 mmol/L; Leukocytes 2.7 ×10⁹/L; Absolute Neutrophil 1.1 ×10⁹/L; Platelets 188 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.13 mmol/L; Albumin 34 g/L; Total Protein 6.1 g/dL; Glucose 4.9 mmol/L.
- Day 309 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.97 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.99 mg/dL; Immunoglobulin G 7.67 g/L; Immunoglobulin A 1.05 g/L; Immunoglobulin M 0.34 g/L; Hemoglobin 7.75 mmol/L; Leukocytes 4.6 ×10⁹/L; Absolute Neutrophil 2.9 ×10⁹/L; Platelets 186 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 7.85 mmol/L; Calcium 2.25 mmol/L; Albumin 44.3 g/L; Total Protein 6.5 g/dL; Glucose 5.17 mmol/L.
- Day 403 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.99 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.05 mg/dL; Immunoglobulin G 7.72 g/L; Immunoglobulin A 1.2 g/L; Immunoglobulin M 0.63 g/L; Hemoglobin 8.12 mmol/L; Leukocytes 5.7 ×10⁹/L; Absolute Neutrophil 4.1 ×10⁹/L; Platelets 181 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.35 mmol/L; Albumin 40.9 g/L; Total Protein 6.3 g/dL; Glucose 6.99 mmol/L.
- Day 494 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.94 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1 mg/dL; Immunoglobulin G 7.01 g/L; Immunoglobulin A 1.19 g/L; Immunoglobulin M 0.72 g/L; Hemoglobin 8.43 mmol/L; Leukocytes 4.5 ×10⁹/L; Absolute Neutrophil 3.5 ×10⁹/L; Platelets 216 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.25 mmol/L; Albumin 39 g/L; Total Protein 6.1 g/dL; Glucose 5.17 mmol/L.
- Day 585 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 1.11 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.21 mg/dL; Immunoglobulin G 8.45 g/L; Immunoglobulin A 0.95 g/L; Immunoglobulin M 0.79 g/L; Hemoglobin 8.56 mmol/L; Leukocytes 6 ×10⁹/L; Absolute Neutrophil 4.8 ×10⁹/L; Platelets 206 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.33 mmol/L; Albumin 39 g/L; Total Protein 6.1 g/dL; Glucose 5.28 mmol/L.
- Day 678 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 1.32 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.42 mg/dL; Immunoglobulin G 8.28 g/L; Immunoglobulin A 1.79 g/L; Immunoglobulin M 0.68 g/L; Hemoglobin 8.49 mmol/L; Leukocytes 3.8 ×10⁹/L; Platelets 224 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.25 mmol/L; Albumin 39 g/L; Total Protein 6.7 g/dL; Glucose 5.45 mmol/L.
- Day 775 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.93 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.19 mg/dL; Immunoglobulin G 9.05 g/L; Immunoglobulin A 5.82 g/L; Immunoglobulin M 0.72 g/L; Hemoglobin 8.56 mmol/L; Leukocytes 4.8 ×10⁹/L; Absolute Neutrophil 3.3 ×10⁹/L; Platelets 217 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.18 mmol/L; Albumin 40.3 g/L; Total Protein 6.8 g/dL; Glucose 4.35 mmol/L.
- Day 834 (ECOG 0): M Protein 1.54 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 6.44 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.98 mg/dL; Immunoglobulin G 6.8 g/L; Immunoglobulin A 10.5 g/L; Immunoglobulin M 0.51 g/L; Hemoglobin 8.49 mmol/L; Leukocytes 3.9 ×10⁹/L; Absolute Neutrophil 2.8 ×10⁹/L; Platelets 208 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.1 mmol/L; Albumin 39 g/L; Total Protein 7.1 g/dL; Glucose 3.63 mmol/L.
- Day 950 (ECOG 0): M Protein 2.43 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 5.76 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.89 mg/dL; Immunoglobulin G 5.46 g/L; Immunoglobulin A 19.4 g/L; Immunoglobulin M 0.29 g/L; Hemoglobin 8 mmol/L; Leukocytes 4.7 ×10⁹/L; Absolute Neutrophil 2.6 ×10⁹/L; Platelets 200 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.15 mmol/L; Albumin 30 g/L; Total Protein 7.6 g/dL; Glucose 10.3 mmol/L.
- Day 1,056 (ECOG 0): M Protein 3.67 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 6.67 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.36 mg/dL; Immunoglobulin G 4.59 g/L; Immunoglobulin A 34.2 g/L; Immunoglobulin M 0.19 g/L; Hemoglobin 7.44 mmol/L; Leukocytes 3.2 ×10⁹/L; Absolute Neutrophil 2.1 ×10⁹/L; Platelets 178 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.13 mmol/L; Albumin 34.1 g/L; Total Protein 8.2 g/dL; Glucose 5.01 mmol/L.
- Day 1,133 (ECOG 0): M Protein 1.51 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 7.85 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.81 mg/dL; Immunoglobulin G 4.07 g/L; Immunoglobulin A 19.5 g/L; Immunoglobulin M 0.21 g/L; Hemoglobin 7.32 mmol/L; Leukocytes 4.1 ×10⁹/L; Absolute Neutrophil 1.8 ×10⁹/L; Platelets 142 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.03 mmol/L; Albumin 30 g/L; Total Protein 7.3 g/dL; Glucose 5.39 mmol/L.
- Day 1,245 (ECOG 0): M Protein 1.84 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 8.61 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.73 mg/dL; Immunoglobulin G 3.06 g/L; Immunoglobulin A 21 g/L; Immunoglobulin M 0.11 g/L; Beta 2 Microglobulin 2.65 µg/mL; Hemoglobin 7.32 mmol/L; Leukocytes 2.4 ×10⁹/L; Absolute Neutrophil 1.1 ×10⁹/L; Platelets 140 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.1 mmol/L; Albumin 29 g/L; Total Protein 7.1 g/dL; Glucose 7.43 mmol/L.
- Day 1,345 (ECOG 0): M Protein 3.63 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 6.88 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.68 mg/dL; Immunoglobulin G 2.39 g/L; Immunoglobulin A 39.3 g/L; Immunoglobulin M 0.07 g/L; Hemoglobin 7.01 mmol/L; Leukocytes 2.4 ×10⁹/L; Absolute Neutrophil 1 ×10⁹/L; Platelets 173 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 0.107 mmol/L; Calcium 2.13 mmol/L; Albumin 28 g/L; Total Protein 9.4 g/dL; Glucose 5.28 mmol/L.

Other clinical attributes
- Day -7: Weight: 82 kg; Height: 163 cm.

Family history
- Relative with cancer history: yes; Relationship type: Maternal Grandfather; Relationship sex at birth: male.

Biospecimens (1 sample)
- Sample MMRF_1504_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -7 days.
